CCDI case PBCDPG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/e24c1a3d-c05a-4075-8102-53cf2231be74

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 19.3 years (7,041 days).

Biospecimens (3 samples)
- Sample 0DPJS9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPJSK, 0DPJT5 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
